Surgical pathology report (de-identified scan), TCGA case TCGA-DU-8168, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-8168-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

Patient Name: [REDACTED]

Med: Rec.: [REDACTED]

DOB: [REDACTED]

Client: [REDACTED]

Accession #: [REDACTED]

Phone Number: [REDACTED]

Gender: F

Location: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

=====

CLINICAL HISTORY

[REDACTED] woman has experienced headaches and difficulty with tasks at work for a few weeks. On imaging, there is a right frontal lesion that is mostly non-enhancing, but has internal nodular enhancing areas. The tumor extends to the body of the corpus callosum and minimally into the contralateral frontal lobe.

OPERATIVE DIAGNOSES

Brain tumor

Operation/Specimen: A: Brain tumor, excision

B: Brain tumor, excision

PATHOLOGICAL DIAGNOSIS:

A, B. Brain, site not specified, excision: Oligodendroglioma, anaplastic (WHO III).

See Microscopy Description and Comment.

COMMENT

The sections contain portions of cerebrum that are moderately to heavily infiltrated by a neoplastic proliferation of glial cells that have a predominantly oligodendroglial phenotype. The neoplastic cells have nuclear anaplastic features, a high mitotic rate of up to 13 mitoses / ten high power fields, and a MIB-1 proliferation index of about 50% in several, more active areas. There is focal microvascular mineralization. There is not appreciable microvascular cellular proliferation, and tumor necrosis is absent.

The features are those of an anaplastic oligodendroglioma (WHO III).

[page 2 of 5]
=====

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is detected.

Informative loci are: D1S552, D1S1612, D19S412 and PLA2G4C.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block
DNA extracted from a corresponding blood specimen was used as a normal reference control.

H slide was examined and no micro dissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

[page 3 of 5]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[REDACTED]
MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

[page 4 of 5]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain tumor, biopsy: Glial neoplasm, with microcalcifications, very cellular

(C/W oligodendroglioma, high histological grade ?). [REDACTED] Touch preparation

smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

"Brain tumor," received fresh, several fragments, 3 cm across in aggregate.

Soft, greyish-purple, glistening, and somewhat diffluent. In total, A1-A3.

B.

Brain tumor, excision:

CONTAINER LABEL: brain tumor.

FIXATIVE: Formalin. NO. PIECES: several pale red tan soft fragments.

SIZE/VOL: 15 x 14 x 7 mm. in aggregate CASSETTES: 1, NS.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a somewhat sparse gliofibrillary background, except in a zone where there are frequent gliofibrillary oligodendrocytes and mini gemistocytes. The synaptophysin, NeuN, NSE, and

neurofilament highlight the moderate to heavy infiltration of the tumor in the

cerebral cortex. The DC99 and EMA weakly react with the neuropil. Only

a small minority of neoplastic cells appreciably over expresses the p53

protein. The CD34 demonstrates a rather organoid microvascular network with

focal hyperplastic areas. With the MIB-1 there is a proliferation index of

about 50% in the more active areas.

[page 5 of 5]
ICD-9(s):
225.0 225.0

Histo Data

Part A: Brain tumor, excision

Taken: [REDACTED]	Received: [REDACTED]	
Stain/cnt	Block Ordered Comment	
CD31-DA x 1	1 [REDACTED]	
EMA-DA x 1	1 [REDACTED]	No charge
mGFAP-DA x 1	1 [REDACTED]	
H/E x 1	1 [REDACTED]	
LOH-curles x 1	1 [REDACTED]	
MGMT-curles x 1	1 [REDACTED]	
MIB1-DA x 1	1 [REDACTED]	
CD99-DA x 1	1 [REDACTED]	No charge
NeuN x 1	1 [REDACTED]	
NF2F11 x 1	1 [REDACTED]	No charge.
NSE-DA x 1	1 [REDACTED]	No charge
P53DO7 x 1	1 [REDACTED]	
Synap-DA x 1	1 [REDACTED]	
H/E x 1	2 [REDACTED]	
H/E x 1	3 [REDACTED]	

Part B: Brain tumor, excision

Taken: [REDACTED]	Received: [REDACTED]	
Stain/cnt	Block Ordered Comment	
H/E x 1	1 [REDACTED]	

Source: NCI Genomic Data Commons file f338e443-fef9-416f-992e-77a49fdc061e (TCGA-DU-8168.E96918FC-F639-46EB-B87A-769402A4D1AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).